Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A102, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A102-01A (Primary Tumor).

[page 1 of 4]
1/17/11 *lw***DIAGNOSIS:**

A. Skin and subcutaneous tissue, abdomen, excision: Skin and subcutaneous tissue (2145.0 grams) with umbilicus identified grossly.

B. Uterus, bilateral ovaries, and fallopian tubes; hysterectomy and bilateral salpingo-oophorectomy: FIGO grade II (of III) endometrial adenocarcinoma, endometrioid type, is identified forming a mass (8.0 x 7.0 x 1.0 cm), circumferentially involving the endometrial cavity. The tumor invades 0.5 cm into the myometrium (total wall thickness, 4.0 cm). The tumor does not involve the endocervix. Lymphovascular space invasion is not identified. The margins are negative for tumor. A single intramural leiomyoma (measuring 7.0 x 6.0 x 6.0 cm) is present. The left ovary shows a benign strumal carcinoid, forming a 1.1 x 1.0 x 1.0 cm mass. The right ovary is absent.

C. D. E. F. Lymph nodes, right pelvic, excision: Multiple right pelvic lymph nodes (2 external iliac, 2 internal iliac, 1 common iliac, and 16 obturator) are negative for tumor.

G. H. I. J. Lymph nodes, left pelvic, excision: Multiple left pelvic lymph nodes (5 external iliac, 1 internal iliac, 6 common iliac, and 12 obturator) are negative for tumor.

GROSS DESCRIPTION:UID:9983D576-706A-48D2-93EE-70EAB83BD77C

[page 2 of 4]
A. Received fresh labeled "pannus" is a 2145.0 gram portion of skin and subcutaneous tissue, with umbilicus. No lesions identified.
Gross Only.

B. Received fresh labeled "uterus, ovaries and fallopian tubes" is a 890.0 gram uterus with attached bilateral tubes and ovaries and an unremarkable cervix. The uterine serosa is smooth. There is an 8.0 x 7.0 x 1.0 cm polypoid yellow mass in the uterine cavity with 4.0 cm myometrial thickness. There is one uterine intramural leiomyoma, 7.0 x 7.0 x 6.0 cm). There is a no right ovary with an 8.0 x 0.4 cm right fallopian tube. There is a 6.0 x 4.0 x 2.5 cm left ovary with a smooth, solid cut surface with a 1.1 x 1.0 x 1.0 cm mass, and a 10.0 x 2.0 cm left fallopian tube. Representative sections submitted.

C. Received fresh labeled "right pelvic external iliac" is a 5.0 x 4.0 x 1.0 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted. Grossed by .

D. Received fresh labeled "right pelvic internal iliac" is a 4.0 x 4.0 x 1.0 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

E. Received fresh labeled "right obturator" is a 6.0 x 4.0 x 1.0 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

F. Received fresh labeled "right common iliac" is a 3.0 x 2.0 x 1.0

[page 3 of 4]
cm aggregate of adipose and lymphatic tissue. All
lymphatic tissue
submitted.

G. Received fresh labeled "left pelvic external iliac" is
an 8.0 x
6.0 x 2.0 cm aggregate of adipose and lymphatic tissue.
All
lymphatic tissue submitted.

H. Received fresh labeled "left pelvic internal iliac" is
an 0.8 x
0.8 x 0.2 cm aggregate of adipose and lymphatic tissue.
All
lymphatic tissue submitted.

I. Received fresh labeled "left obturator" is a 5.0 x 3.0
x 1.5 cm
aggregate of adipose and lymphatic tissue. All lymphatic
tissue
submitted.

J. Received fresh labeled "left common iliac" is a 2.0 x
2.0 x 0.7
cm aggregate of adipose and lymphatic tissue. All
lymphatic tissue
submitted.

BLOCK SUMMARY:

Part A: Pannus

Part B: Uterus, tubes, ovaries

- 1 Endometrial tumor-1
- 2 Endometrial tumor-2
- 3 Endometrial tumor-3
- 4 Endometrial tumor-4
- 5 6:00 Cervix
- 6 Myometrium
- 7 Lt ovary with tumor
- 8 Lt ovary
- 9 Lt fallopian tube
- 10 Rt fallopian tube

Part C: Right Pelvic Lymph Nodes external

- 1 Rt external lns-1(C1)
- 2 Rt external lns-1(C2)

[page 4 of 4]
Part D: Right Pelvic Lymph Nodes internal

- 1 Rt internal lns-2(D1)

Part E: Right Pelvic Lymph Nodes obturator

- 1 Rt obturator lns-3(E1)
- 2 Rt obturator lns-4(E2)
- 3 Rt obturator lns-2(E3)
- 4 Rt obturator lns-3(E4)
- 5 Rt obturator lns-3(E5)
- 6 Rt obturator lns-1of2(E6)
- 7 Rt obturator lns-2of2(E6)

Part F: Right Pelvic Lymph Nodes common

- 1 Rt common lns-1(F1)

Part G: Left Pelvic Lymph Nodes external

- 1 Lt ext LN2(G1)
- 2 Lt ext LN2(G2)

Part H: Left Pelvic Lymph Nodes internal

- 1 Lt int LN1(H1)

Part I: Left Pelvic Lymph Nodes obturator

- 1 Lt obt LN3(I1)
- 2 Lt obt LN6(I2)
- 3 Lt obt LN3(I3)

Part J: Left Pelvic Lymph Nodes common

- 1 Lt common lns-3(J1)
- 2 Lt common lns-3(J2)

Source: NCI Genomic Data Commons file 84370a7c-05d0-4064-b75c-2fe6937ff822 (TCGA-D1-A102.9983D576-706A-48D2-93EE-70EABB3BD77C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).